Somatic mutation profile of tumor specimen TCGA-LN-A4A9-01A (aliquot TCGA-LN-A4A9-01A-11D-A28B-09) from TCGA case TCGA-LN-A4A9, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G1; Age at diagnosis: 58.1 years (21,217 days).
Specimen TCGA-LN-A4A9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7cc2343e-3615-4003-bf87-6f21ad24a635.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LN-A4A9-10A (Blood Derived Normal), aliquot TCGA-LN-A4A9-10A-01D-A28E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/abd24e3c-8cf7-4cdb-8369-5e26d3ed6ebc

The open-access MAF lists 219 somatic variants for this specimen: 169 protein-altering or splice-affecting, 48 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 148, Silent 48, Nonsense Mutation 10, Splice Region 3, Frame Shift Ins 2, Nonstop Mutation 2, In Frame Del 2, Intron 1, Splice Site 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.402T>A p.F134L | Missense Mutation (SNP) | VAF 34/47 reads (72%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52723236, COSV52814502, COSV52902300; called by muse, mutect2, varscan2
- ZNF341 | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 11/65 reads (17%) | catalogued as rs1568940507; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAD2 | c.632G>A p.R211H (on ENST00000315906 / NM_001145400.2; = p.R283H on NM_139174.4) | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.551); catalogued as rs568492054, COSV51893155; called by muse, mutect2, varscan2
- ANKEF1 | c.1615G>C p.D539H | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.373); catalogued as COSV65692652; called by muse, mutect2, varscan2
- ASXL2 | c.1555G>C p.E519Q | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV55468830, COSV55469533; called by muse, mutect2, varscan2
- BRD8 | c.2081C>G p.S694* (on ENST00000254900 / NM_139199.2; = p.S767* on NM_006696.4) | Nonsense Mutation (SNP) | VAF 31/87 reads (36%) | catalogued as COSV50147701; called by muse, mutect2, varscan2
- C3orf20 | c.1090C>G p.Q364E | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.397); catalogued as COSV53787144, COSV53788331; called by muse, mutect2, varscan2
- C8A | c.1453C>A p.R485S | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as COSV100776627; called by muse, mutect2, varscan2
- CAPRIN1 | c.1811A>G p.Y604C | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs763927685; called by muse, mutect2, varscan2
- CEACAM21 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.399); catalogued as rs1555790999; called by muse, mutect2, varscan2
- CFAP91 | c.260C>G p.S87C | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); catalogued as COSV56342652, COSV56343156; called by muse, mutect2, varscan2
- CRYBG1 | c.5315G>C p.W1772S | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64813574; called by muse, mutect2, varscan2
- CYTH2 | c.432C>T p.L144= | Splice Region (SNP) | VAF 12/42 reads (29%) | catalogued as rs758032912; called by muse, mutect2, varscan2
- DEFB108B | c.36C>G p.F12L | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.636); catalogued as COSV100156794; called by muse, mutect2, varscan2
- EPRS1 | c.3380A>G p.Y1127C | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100859351; called by muse, mutect2, varscan2
- FBXL13 | c.2029C>G p.Q677E | Missense Mutation (SNP) | VAF 50/182 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV57537115; called by muse, mutect2, varscan2
- FBXW5 | c.236C>T p.T79M | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs775883396; called by muse, mutect2, varscan2
- FCRL1 | c.352C>G p.Q118E | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.371); catalogued as COSV63824758; called by muse, mutect2, varscan2
- FCRL6 | c.14C>T p.T5M | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs750496573, COSV58942548; called by muse, mutect2, varscan2
- FIGN | c.1514C>A p.P505Q | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60771668; called by muse, mutect2, varscan2
- GLI3 | c.1763C>G p.S588* | Nonsense Mutation (SNP) | VAF 49/182 reads (27%) | catalogued as COSV67892394; called by muse, mutect2, varscan2
- H1-10 | c.194C>G p.S65W | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61549553; called by muse, mutect2, varscan2
- HECTD4 | c.12064G>A p.E4022K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.037); catalogued as COSV66388681; called by muse, mutect2, varscan2
- HGF | c.782G>T p.R261L | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55947351, COSV55955898; called by muse, mutect2, varscan2
- IFNL2 | c.11A>G p.D4G | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as rs778693588; called by muse, mutect2, varscan2
- IFT80 | c.149T>C p.I50T | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as rs768189853; called by muse, mutect2, varscan2
- ING5 | c.649G>T p.V217L | Missense Mutation (SNP) | VAF 101/131 reads (77%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV57979957; called by muse, mutect2, varscan2
- ITGAV | c.1774C>T p.R592W | Missense Mutation (SNP) | VAF 26/36 reads (72%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs200949549, COSV53709675; called by muse, mutect2, varscan2
- KCNN2 | c.617G>A p.R206K (on ENST00000264773; = p.R418K on NM_021614.4) | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV99298485; called by muse, mutect2, varscan2
- KDM7A | c.2503G>C p.E835Q | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.037); catalogued as rs747849530; called by muse, mutect2, varscan2
- KRTAP5-1 | c.282_311del p.C112_S121del | In Frame Del (DEL) | VAF 22/60 reads (37%) | catalogued as rs777853655; called by muse*, mutect2
- LYG2 | c.530C>A p.S177* | Nonsense Mutation (SNP) | VAF 18/33 reads (55%) | catalogued as COSV100283489; called by muse, mutect2, varscan2
- MDC1 | c.1871G>C p.G624A | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.113); catalogued as rs746258696; called by muse, mutect2, varscan2
- MPL | c.213G>A p.R71= | Splice Region (SNP) | VAF 14/113 reads (12%) | catalogued as COSV100991446; called by muse, mutect2, varscan2
- NDST4 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.033); catalogued as COSV52126352; called by muse, mutect2, varscan2
- NECTIN3 | c.1292G>A p.R431K | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV100162572, COSV60552207; called by muse, mutect2, varscan2
- NHLRC2 | c.238A>G p.I80V | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100800360; called by muse, mutect2, varscan2
- NUDCD3 | c.149G>T p.R50L | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs867641636, COSV62647726; called by muse, mutect2, varscan2
- NUDT16 | c.508C>A p.Q170K | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as rs966286426; called by muse, mutect2, varscan2
- OR4N2 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 56/125 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs770622276, COSV60050519; called by muse, mutect2, varscan2
- OR6N2 | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as rs753611659, COSV59410730; called by muse, mutect2, varscan2
- PAPSS2 | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1246013772; called by muse, mutect2, varscan2
- PATJ | c.998C>T p.S333L | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV57160117; called by muse, mutect2
- PCDHA13 | c.132C>G p.F44L | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.259); catalogued as COSV56480548; called by muse, mutect2, varscan2
- PCDHGA8 | c.2152C>T p.R718C | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.046); catalogued as COSV53914356; called by muse, mutect2
- PDP1 | c.1270A>G p.M424V | Missense Mutation (SNP) | VAF 60/276 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.173); catalogued as rs1260117347; called by muse, mutect2, varscan2
- PON2 | c.675C>G p.I225M | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56001907; called by muse, mutect2, varscan2
- PRKAG3 | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 67/95 reads (71%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV52102598; called by muse, mutect2, varscan2
- PRSS53 | c.293A>C p.Q98P | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as rs1051052208; called by muse, mutect2, varscan2
- PTP4A3 | c.313G>T p.V105L | Missense Mutation (SNP) | VAF 165/273 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV100267440, COSV61471428; called by muse, mutect2, varscan2
- PUDP | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 84/96 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs1317270882; called by muse, mutect2, varscan2
- RHOA | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV69042035, COSV69043179; called by muse, mutect2, varscan2
- RPL34 | c.342G>C p.Q114H | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1065701; called by muse, mutect2, varscan2
- SLC5A3 | c.559C>G p.L187V | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as COSV62968002; called by muse, mutect2, varscan2
- SNRPF | c.218G>C p.R73T | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.457); catalogued as COSV99900104; called by muse, mutect2, varscan2
- SPECC1L | c.3121A>G p.N1041D | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100063424; called by muse, mutect2, varscan2
- TACC3 | c.1564G>C p.E522Q | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.769); catalogued as COSV57606411; called by muse, mutect2, varscan2
- TAF2 | c.1964A>G p.Y655C | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1201609908; called by muse, mutect2, varscan2
- TAF5 | c.59C>A p.P20Q | Missense Mutation (SNP) | VAF 27/37 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs1336500274; called by muse, mutect2, varscan2
- TEAD4 | c.124G>T p.V42L | Missense Mutation (SNP) | VAF 44/61 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63280733; called by muse, mutect2, varscan2
- TIMELESS | c.18G>A p.M6I | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as rs1467514517; called by muse, mutect2, varscan2
- TMEM132D | c.2594A>C p.K865T | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV101242707, COSV67158649; called by muse, mutect2, varscan2
- TOB1 | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV99278848; called by muse, mutect2, varscan2
- URB2 | c.1106A>G p.N369S | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1162753578, COSV51027965; called by muse, mutect2, varscan2
- WASHC5 | c.1602G>A p.M534I | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); catalogued as COSV104403204; called by muse, mutect2
- ZNF431 | c.418G>C p.E140Q | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.175); catalogued as rs181764553, COSV60671994, COSV60673036; called by muse, mutect2, varscan2
- ZNF534 | c.490A>C p.S164R (on ENST00000332323 / NM_001143939.3; = p.S151R on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.149); catalogued as rs1568444326, COSV56520724; called by muse, mutect2, varscan2
- A2M | c.1485C>G p.F495L | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- ABCA13 | c.10603A>C p.I3535L | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- ABCA7 | c.1059G>C p.Q353H | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADAM20 | c.1113G>T p.K371N | Missense Mutation (SNP) | VAF 55/73 reads (75%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADGRB3 | c.819A>T p.K273N | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AKAP13 | c.6769G>A p.D2257N (on ENST00000394518 / NM_007200.5; = p.D2261N on NM_006738.6) | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- APP | c.318G>T p.K106N | Missense Mutation (SNP) | VAF 67/94 reads (71%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- BMP15 | c.230C>G p.S77* | Nonsense Mutation (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
- CARS1 | c.566A>T p.E189V | Missense Mutation (SNP) | VAF 29/39 reads (74%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- CDAN1 | c.85T>G p.S29A | Missense Mutation (SNP) | VAF 36/57 reads (63%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- CGREF1 | c.898G>T p.E300* (on ENST00000260595; = p.E317* on NM_006569.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 15/60 reads (25%) | called by muse, mutect2, varscan2
- COL11A2 | c.1360-2A>G p.X454_splice (on ENST00000341947 / NM_080680.3; = p.X347_splice on NM_080679.2) | Splice Site (SNP) | VAF 13/46 reads (28%) | called by muse, mutect2, varscan2
- CPZ | c.242T>G p.L81R (on ENST00000360986 / NM_001014447.3; = p.L70R on NM_003652.3) | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAH9 | c.6814C>G p.R2272G | Missense Mutation (SNP) | VAF 33/52 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- EEA1 | c.4204T>G p.C1402G | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EHD1 | c.978C>G p.S326R | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EIF4H | c.25G>C p.D9H | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- ERAP1 | c.747C>A p.F249L | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.169); called by muse, varscan2
- EXOC6 | c.1084G>A p.D362N | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- FBF1 | c.2073G>T p.M691I (on ENST00000586717; = p.M705I on NM_001319193.1) | Missense Mutation (SNP) | VAF 89/112 reads (79%) | SIFT tolerated (0.13); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FBXO41 | c.1866G>C p.L622F | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FOXD2 | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GGNBP2 | c.478A>T p.K160* | Nonsense Mutation (SNP) | VAF 37/50 reads (74%) | called by muse, mutect2
- GGNBP2 | c.480G>T p.K160N | Missense Mutation (SNP) | VAF 37/50 reads (74%) | SIFT deleterious (0.04); PolyPhen benign (0.028); called by muse, mutect2
- GHSR | c.976dup p.M326Nfs*29 | Frame Shift Ins (INS) | VAF 27/85 reads (32%) | called by mutect2, pindel, varscan2
- GPR83 | c.64G>T p.G22C | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.078); called by muse, varscan2
- GPRC6A | c.2170A>C p.I724L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GRAMD4 | c.1592C>G p.S531* | Nonsense Mutation (SNP) | VAF 16/89 reads (18%) | called by muse, mutect2, varscan2
- GRIP1 | c.1481C>A p.T494K (on ENST00000359742 / NM_001379345.1; = p.T442K on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- GSTT2B | c.544G>C p.E182Q | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HAUS4 | c.931C>G p.H311D | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- HCAR2 | c.414G>C p.K138N | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- HCLS1 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- IGSF9B | c.3554G>T p.R1185M | Missense Mutation (SNP) | VAF 88/120 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- IL4R | c.492G>C p.W164C | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- KDM5A | c.3340G>A p.E1114K | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KLHDC1 | c.890G>A p.R297K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, varscan2
- KMT2B | c.2412C>G p.F804L | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2
- LIAS | c.299G>T p.W100L (on ENST00000261434 / NM_001363700.2; = p.M131I on NM_006859.4) | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- LIG3 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- MAP10 | c.2942C>A p.S981Y | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- MAST3 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- MEI1 | c.3136A>T p.S1046C | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MLLT3 | c.1123G>A p.D375N | Missense Mutation (SNP) | VAF 37/57 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- MYH6 | c.2200G>A p.E734K | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- MYO9B | c.1088A>T p.Y363F | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NCAM1 | c.1532C>A p.S511Y (on ENST00000316851 / NM_181351.5; = p.S501Y on NM_000615.7) | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NCOR1 | c.2656G>A p.D886N | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NLRP2 | c.2399G>T p.W800L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- NUP88 | c.2201A>G p.D734G | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- OMA1 | c.136A>G p.I46V | Missense Mutation (SNP) | VAF 73/358 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PALM2AKAP2 | c.651C>G p.H217Q (on ENST00000374531 / NM_001037293.2; = p.H249Q on NM_053016.6) | Missense Mutation (SNP) | VAF 36/41 reads (88%) | SIFT tolerated (0.67); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PARP1 | c.686A>T p.D229V | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCMT1 | c.857G>C p.*286Sext*78 | Nonstop Mutation (SNP) | VAF 10/21 reads (48%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.82C>A p.Q28K | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PODXL | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 31/195 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PPL | c.1719C>G p.F573L | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2
- PPP1R14D | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PPP4R1 | c.2479G>C p.E827Q (on ENST00000400556 / NM_001042388.3; = p.E810Q on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- PRSS21 | c.835G>C p.E279Q | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.02); called by muse, mutect2
- PRSS58 | c.726A>T p.*242Cext*18 | Nonstop Mutation (SNP) | VAF 13/25 reads (52%) | called by muse, mutect2, varscan2
- PVR | c.263A>T p.E88V | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- RAD52 | c.1091_1102del p.M364_Q367del | In Frame Del (DEL) | VAF 17/53 reads (32%) | called by mutect2, pindel, varscan2
- RDH16 | c.547G>T p.V183L | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- RIMS1 | c.4318G>T p.A1440S | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- RNF169 | c.1315C>T p.Q439* | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- SEPHS2 | c.685G>C p.V229L | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- SERPINI2 | c.257T>G p.F86C | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SEZ6L | c.3000G>C p.Q1000H | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC12A1 | c.2502A>T p.L834F | Missense Mutation (SNP) | VAF 33/44 reads (75%) | SIFT tolerated (0.71); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- STMN1 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STXBP5L | c.656G>C p.R219T | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- SYCP2L | c.1589C>A p.S530* | Nonsense Mutation (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- SYNDIG1 | c.473A>G p.E158G | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.417); called by muse, mutect2
- SZT2 | c.6049G>A p.E2017K (on ENST00000634258 / NM_001365999.1; = p.E1960K on NM_015284.4) | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- TCF20 | c.2008G>T p.D670Y | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- TEX11 | c.761T>C p.M254T (on ENST00000344304; = p.M239T on NM_031276.3) | Missense Mutation (SNP) | VAF 34/46 reads (74%) | SIFT tolerated (0.1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- THPO | c.1288C>T p.P430S (on ENST00000649095 / NM_001290003.1; = p.P290S on NM_000460.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- TIGD4 | c.1125dup p.E376* | Frame Shift Ins (INS) | VAF 19/76 reads (25%) | called by mutect2, pindel, varscan2
- TIGD5 | c.234C>G p.C78W | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- TLE6 | c.550C>T p.P184S (on ENST00000246112 / NM_001143986.2; = p.P61S on NM_024760.3) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TLR4 | c.1401C>A p.F467L (on ENST00000355622 / NM_138554.5; = p.F427L on NM_003266.4) | Missense Mutation (SNP) | VAF 41/51 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TPRG1 | c.259G>C p.E87Q | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TRAV16 | c.270C>G p.H90Q | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- TRMT10C | c.394T>C p.Y132H | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- TRPC6 | c.2646G>T p.G882= | Splice Region (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
- TTC16 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.02); called by muse, varscan2
- TTC7B | c.1629G>T p.Q543H | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- UMPS | c.1150A>G p.R384G | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- UPF3B | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- USP21 | c.1194T>G p.C398W | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- USP3 | c.1046G>C p.R349T | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- USP45 | c.1519C>T p.P507S | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- VCP | c.252G>A p.M84I | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VEPH1 | c.1228C>A p.Q410K | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- VPS36 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- WDR33 | c.3001G>A p.D1001N | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- ZAN | c.263A>C p.Y88S | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF395 | c.1387C>T p.H463Y | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- ZNF467 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF625 | c.912A>C p.E304D | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF750 | c.688del p.A230Pfs*136 | Frame Shift Del (DEL) | VAF 66/109 reads (61%) | called by mutect2, pindel, varscan2
- ACTRT3 | c.333A>G p.P111= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as rs1306253625; called by muse, mutect2, varscan2
- AGK | c.288T>A p.T96= | Silent (SNP) | VAF 13/51 reads (25%) | called by muse, mutect2, varscan2
- AOX1 | c.81G>C p.L27= | Silent (SNP) | VAF 44/112 reads (39%) | catalogued as rs1221725301; called by muse, mutect2, varscan2
- ARAP2 | c.3558G>C p.T1186= | Silent (SNP) | VAF 25/48 reads (52%) | catalogued as rs771824573, COSV58286969, COSV58291066; called by muse, mutect2, varscan2
- ATP1A2 | c.480G>A p.K160= | Silent (SNP) | VAF 49/109 reads (45%) | called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.927C>G p.T309= | Silent (SNP) | VAF 16/37 reads (43%) | called by muse, mutect2, varscan2
- CHID1 | c.1137C>T p.I379= | Silent (SNP) | VAF 21/60 reads (35%) | called by muse, mutect2, varscan2
- CHST11 | c.180G>T p.L60= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV57996148; called by muse, mutect2, varscan2
- CIC | c.3171C>T p.L1057= | Silent (SNP) | VAF 5/21 reads (24%) | called by muse, mutect2, varscan2
- CTDSPL2 | c.960C>A p.V320= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV52947136; called by muse, mutect2
- CUX2 | c.1491C>T p.F497= | Silent (SNP) | VAF 12/17 reads (71%) | called by muse, mutect2, varscan2
- DEFB123 | c.69A>G p.Q23= | Silent (SNP) | VAF 18/64 reads (28%) | called by muse, mutect2, varscan2
- DLGAP2 | c.1263C>T p.T421= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as rs374538901; called by muse, mutect2, varscan2
- DST | c.6396C>G p.L2132= | Silent (SNP) | VAF 20/52 reads (38%) | called by muse, mutect2, varscan2
- DZIP1L | c.9C>G p.S3= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV59521062; called by muse, mutect2, varscan2
- EPB41L5 | c.2067A>G p.G689= | Silent (SNP) | VAF 34/94 reads (36%) | catalogued as COSV55355770; called by muse, mutect2, varscan2
- FAT1 | c.10836C>G p.L3612= | Silent (SNP) | VAF 18/55 reads (33%) | called by muse, mutect2, varscan2
- GGH | c.165T>C p.Y55= | Silent (SNP) | VAF 30/54 reads (56%) | catalogued as rs780111805; called by muse, mutect2, varscan2
- GH1 | c.534C>T p.N178= | Silent (SNP) | VAF 280/351 reads (80%) | catalogued as rs1356772497; called by muse, mutect2, varscan2
- GRAMD4 | c.36T>C p.G12= | Silent (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2, varscan2
- GSTT2B | c.456G>T p.G152= | Silent (SNP) | VAF 14/30 reads (47%) | called by mutect2, varscan2
- GTF2H1 | c.528C>G p.P176= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as rs1383222973; called by muse, mutect2, varscan2
- GTF3C3 | c.96G>A p.E32= | Silent (SNP) | VAF 19/58 reads (33%) | called by muse, mutect2, varscan2
- HELZ2 | c.5221C>T p.L1741= (on ENST00000467148 / NM_001037335.2; = p.L1172= on NM_033405.3) | Silent (SNP) | VAF 11/22 reads (50%) | called by muse, mutect2, varscan2
- HGF | c.783C>T p.R261= | Silent (SNP) | VAF 37/82 reads (45%) | called by muse, mutect2, varscan2
- INSL6 | c.69G>A p.L23= | Silent (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2, varscan2
- ITPR1 | c.684T>C p.D228= | Silent (SNP) | VAF 17/62 reads (27%) | called by muse, mutect2, varscan2
- KAT6A | c.1707G>A p.E569= | Silent (SNP) | VAF 17/60 reads (28%) | called by muse, mutect2, varscan2
- LMO7 | c.3024G>A p.G1008= (on ENST00000357063; = p.G689= on NM_005358.5) | Silent (SNP) | VAF 17/55 reads (31%) | called by muse, mutect2, varscan2
- LRP1B | c.10779T>C p.T3593= | Silent (SNP) | VAF 11/31 reads (35%) | called by muse, mutect2, varscan2
- MAGEB6B | c.780G>A p.E260= | Silent (SNP) | VAF 31/90 reads (34%) | called by muse, mutect2, varscan2
- MAP3K6 | c.1848C>A p.I616= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as COSV62888677; called by muse, mutect2, varscan2
- MYO18B | c.4848C>A p.A1616= | Silent (SNP) | VAF 24/81 reads (30%) | called by muse, mutect2, varscan2
- OR14C36 | c.744C>T p.V248= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs142764213; called by muse, mutect2, varscan2
- PIP5K1C | c.570C>T p.V190= | Silent (SNP) | VAF 20/62 reads (32%) | called by muse, mutect2, varscan2
- PLA1A | c.1254G>A p.K418= | Silent (SNP) | VAF 25/72 reads (35%) | called by muse, mutect2, varscan2
- PMM1 | c.378A>G p.G126= | Silent (SNP) | VAF 10/41 reads (24%) | called by muse, mutect2, varscan2
- PWWP3A | c.2166C>G p.L722= (on ENST00000627377; = p.S669C on NM_032853.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 20/57 reads (35%) | called by muse, mutect2, varscan2
- RAET1E | c.684C>T p.I228= | Silent (SNP) | VAF 14/38 reads (37%) | called by muse, mutect2
- SOAT1 | c.258A>G p.S86= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs1210583092; called by muse, mutect2, varscan2
- ST18 | c.441A>G p.E147= | Silent (SNP) | VAF 24/64 reads (38%) | called by muse, mutect2, varscan2
- TANGO6 | c.864T>C p.D288= | Silent (SNP) | VAF 39/74 reads (53%) | called by muse, mutect2, varscan2
- TCF25 | c.534C>G p.L178= | Silent (SNP) | VAF 30/84 reads (36%) | called by muse, mutect2
- TICRR | c.3090T>C p.Y1030= | Silent (SNP) | VAF 36/77 reads (47%) | called by muse, mutect2, varscan2
- TIGD7 | c.1617C>T p.F539= | Silent (SNP) | VAF 35/60 reads (58%) | called by muse, mutect2, varscan2
- TKT | c.1038C>G p.T346= | Silent (SNP) | VAF 101/136 reads (74%) | called by muse, mutect2, varscan2
- ZNF579 | c.1512C>A p.L504= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV100329259; called by muse, mutect2
- ZNF883 | c.498A>G p.T166= | Silent (SNP) | VAF 40/58 reads (69%) | catalogued as rs1390715457; called by muse, mutect2, varscan2
- OBSCN | c.11659+4286A>C | Intron (SNP) | VAF 29/92 reads (32%) | called by muse, mutect2, varscan2
- REXO1L1P | n.730C>A | RNA (SNP) | VAF 38/286 reads (13%) | called by muse, mutect2, varscan2
